FM case AD2884 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/feede1c7-7a56-4f76-a29c-18ca51162a27

Female, 55.1 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3). Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Tumor.
